Gene-level copy-number profile of tumor specimen TCGA-BF-AAP1-01A from TCGA case TCGA-BF-AAP1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 86.7 years (31,666 days).
Specimen TCGA-BF-AAP1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.09b74d89-e2b6-45ee-9ba1-49dd9dd59541.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-AAP1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26069b6a-1eac-451e-8f70-2a472671fdf6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,126; copy number 2: 9,359; copy number 3: 12,406; copy number 4: 26,535; copy number 5: 5,608; copy number 6: 157; copy number 7: 1,533; copy number 9: 24; copy number 10: 2,757; copy number 11: 225; copy number 12: 4; copy number 16: 11; copy number 21: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-AAP1-01A-11D-A396-01): tumor purity 0.85, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,095 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 12–21 (broad region; genes not listed).
- chr1:148,290,889–148,519,604, 1 gene, copy number 9 (within-gene range 5–9): LINC01138.
- chr1:148,358,245–149,048,286, 23 genes, copy number 9 (within-gene range 5–9): AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2.
- chr7:70,972–68,119,209, 1,283 genes, copy number 10–16 (broad region; genes not listed).
- chr7:71,779,491–159,233,377, 1,710 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
